Gene-level copy-number profile of tumor specimen C3N-05135-01 from CPTAC case C3N-05135, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 32.2 years (11,750 days).
Specimen C3N-05135-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7cb26e64-65f7-480f-b369-fc24e65478a3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-05135-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,706 have no estimate.
https://portal.gdc.cancer.gov/files/d3c82d2a-f7ae-4811-a6ec-16a6802e9191

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 5,556; copy number 2: 53,277; copy number 3: 43; copy number 5: 36.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:52,452–89,850, 2 genes: AL449043.2, PGM5P3-AS1.
- chr9:1,328,664–1,333,953, 2 genes: AL358934.1, RNA5SP279.
- chr11:4,954,772–4,955,713, 1 gene (within-gene range 0–1): OR51A2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 36 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:18,220,113–18,359,300, 7 genes, copy number 5: GGCTP2, RN7SL14P, RNU2-56P, ZNF133, AL049646.1, RN7SKP74, ZNF133-AS1.
- chr20:25,955,795–26,086,917, 6 genes, copy number 5: LINC01733, FAM182A, AL078587.1, AL078587.2, AL450124.1, BSNDP3.
- chr20:31,819,308–32,439,319, 23 genes, copy number 5: MYLK2, FOXS1, DUSP15, TTLL9, RNU1-94P, PDRG1, XKR7, AL031658.2, AL031658.1, RNA5SP481, CCM2L, RNA5SP482, HCK, TM9SF4, AL049539.1, RSL24D1P6, TSPY26P, PLAGL2, POFUT1, MIR1825, KIF3B, AL121583.1, ASXL1.

Autosomal genes at a single copy (total copy number 1): 2,701. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
